Somatic mutation profile of tumor specimen C3L-08654-05 (aliquot CPT0481970006) from CPTAC case C3L-08654, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.5 years (27,594 days).
Specimen C3L-08654-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65a4d751-c8fd-427f-8773-b1ff9f617fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08654-31 (Blood Derived Normal), aliquot CPT0482080003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/575f75f0-ad3a-4666-8d5c-3fb3e3ee29a7

The open-access MAF lists 163 somatic variants for this specimen: 115 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 42, Nonsense Mutation 6, Intron 4, Frame Shift Ins 3, Frame Shift Del 3, 3'Flank 1, 5'Flank 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN5 | c.848G>T p.R283L (on ENST00000456580; = p.R243L on NM_004055.5) | Missense Mutation (SNP) | VAF 75/481 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as rs397514601, CM129863; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLG | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918030, CM971218, COSV51984776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756407851, COSV63973789; called by muse, mutect2
- ADAMTS2 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370478581, COSV99281776; called by muse, mutect2, varscan2
- AMBRA1 | c.2815C>T p.R939* (on ENST00000458649 / NM_001367468.1; = p.R849* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/209 reads (26%) | catalogued as COSV100093809; called by muse, mutect2, varscan2
- ANKAR | c.961T>G p.F321V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55618846; called by muse, mutect2
- ATP12A | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 70/445 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778588362, COSV54524309; called by muse, varscan2
- BBS5 | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs138097217; called by muse, mutect2, varscan2
- C19orf25 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs570931218; called by muse, mutect2, varscan2
- C2CD4A | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100831030; called by muse, mutect2, varscan2
- CACNA1H | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 70/579 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs568224207, COSV100673742; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALM2 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as COSV55398437; called by muse, mutect2
- CDH9 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.075); catalogued as rs183180776, COSV50461688; called by muse, mutect2
- CEACAM16 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 102/439 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs985644364, COSV69187365; called by muse, mutect2, varscan2
- COG1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs761121843; called by muse, mutect2, varscan2
- CTDP1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50002980; called by muse, mutect2, varscan2
- CYP4F22 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs142720535; called by muse, mutect2, varscan2
- DCSTAMP | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs745726484; called by muse, mutect2, varscan2
- DDIT3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100007736; called by muse, mutect2, varscan2
- DISC1 | c.1792G>T p.G598* | Nonsense Mutation (SNP) | VAF 45/275 reads (16%) | catalogued as COSV99698355; called by muse, mutect2, varscan2
- EPB41L1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 44/540 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99152742; called by muse, mutect2
- ESPN | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762623964, COSV64705403; called by muse, mutect2, varscan2
- FARP1 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 18/339 reads (5%) | catalogued as rs1334282642; called by muse, mutect2
- GAL3ST4 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs373254633; called by muse, mutect2, varscan2
- GOPC | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50000938; called by muse, mutect2, varscan2
- GRIA1 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV53598916; called by muse, varscan2
- IPO5 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1211038216, COSV55156138; called by muse, mutect2
- KIAA1109 | c.7513C>T p.P2505S | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1214600785; called by muse, mutect2, varscan2
- KIAA1755 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs759318204; called by muse, mutect2, varscan2
- LSM11 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760221179; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 119/479 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs746424374; called by muse, mutect2, varscan2
- MYO15A | c.5084C>T p.P1695L | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374622768; called by muse, mutect2, varscan2
- NFATC1 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 145/358 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs773206226, COSV53702662; called by muse, mutect2, varscan2
- NME8 | c.928dup p.M310Nfs*20 | Frame Shift Ins (INS) | VAF 58/306 reads (19%) | catalogued as rs764411137; called by mutect2, varscan2
- NOTCH3 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs1250956327, CM122007; called by muse, mutect2, varscan2
- OCA2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs35764631, CM135778; called by muse, mutect2, varscan2
- OR2T12 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.821); catalogued as COSV58776831; called by muse, mutect2
- PCDHB3 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV50583416; called by muse, mutect2, varscan2
- PCDHGB2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.474); catalogued as rs1366415460, COSV99548238; called by muse, mutect2, varscan2
- PDZD2 | c.8467G>A p.V2823I | Missense Mutation (SNP) | VAF 211/376 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1236137556; called by muse, mutect2, varscan2
- PPP1R3A | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 50/179 reads (28%) | catalogued as rs780306610, COSV52882236; called by muse, mutect2, varscan2
- QARS1 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777332, CM143739, COSV60275491; ClinVar: uncertain significance; called by muse, varscan2
- RP1L1 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 154/383 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs750886173, COSV66752553; called by muse, mutect2, varscan2
- RPSA | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs754451302; called by muse, mutect2, varscan2
- SKA1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776374638; called by muse, mutect2, varscan2
- SLC2A6 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781964271, COSV64143125; called by muse, mutect2, varscan2
- SLC6A13 | c.1062C>T p.G354= | Splice Region (SNP) | VAF 53/195 reads (27%) | catalogued as rs750996271; called by muse, mutect2, varscan2
- SLFN13 | c.1185_1187del p.Q395del | In Frame Del (DEL) | VAF 28/116 reads (24%) | catalogued as rs771967762; called by pindel, varscan2
- SPG7 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs1360651357; called by muse, mutect2
- UBE2O | c.3710G>A p.R1237Q | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs534777947, COSV100039375, COSV100039605; called by muse, mutect2, varscan2
- UFM1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53495108; called by muse, mutect2
- USP6NL | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs766862751; called by muse, mutect2, varscan2
- WDR75 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59106061; called by muse, mutect2, varscan2
- WDR87 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 132/412 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as rs766532444, COSV58203948; called by muse, mutect2, varscan2
- ZNF34 | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs372706528; called by muse, mutect2, varscan2
- ZNF536 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 68/1286 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as rs1249515909, COSV62830106; called by muse, mutect2
- ZNF717 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488697308; called by muse, mutect2, varscan2
- AC011455.2 | c.1667G>C p.G556A | Missense Mutation (SNP) | VAF 110/1057 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ACACB | c.3754G>A p.D1252N | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ADAM22 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ADGRG4 | c.5800G>T p.V1934F | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- AKAP9 | c.4769T>C p.M1590T | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AQP9 | c.37A>C p.K13Q | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ASB1 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- ASIC5 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATAD2B | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ATG7 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BST1 | c.279dup p.I94Yfs*2 | Frame Shift Ins (INS) | VAF 54/205 reads (26%) | called by mutect2, pindel, varscan2
- BTNL8 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- C12orf56 | c.1808G>A p.C603Y (on ENST00000543942 / NM_001170633.2; = p.C443Y on NM_001099676.3) | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD300E | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 177/295 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDRT1 | c.1635_1638del p.Y546Lfs*2 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | called by mutect2, varscan2
- CHD2 | c.5254G>A p.G1752S | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DCAF8 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 57/552 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DNAAF3 | c.1384C>A p.L462M (on ENST00000524407 / NM_001256715.2; = p.L509M on NM_178837.4) | Missense Mutation (SNP) | VAF 104/461 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.607); called by muse, varscan2
- FAM110D | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- FAM120A | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- FAM193A | c.2349G>C p.Q783H | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT1 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FSIP2 | c.5944G>A p.D1982N | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIPC3 | c.1061A>G p.Q354R | Missense Mutation (SNP) | VAF 103/310 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- HDLBP | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HIP1 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.167); called by muse, mutect2
- HIVEP3 | c.5152G>A p.D1718N | Missense Mutation (SNP) | VAF 49/617 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2
- HTT | c.5236C>T p.Q1746* | Nonsense Mutation (SNP) | VAF 47/149 reads (32%) | called by muse, mutect2, varscan2
- IKBKB | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 44/541 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- ITGAE | c.3520C>G p.L1174V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MLH1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.5995A>G p.S1999G | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- NEMF | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.436); called by muse, mutect2
- NUTM2F | c.1486-6_1525del p.X496_splice | Splice Site (DEL) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- OR2W3 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 200/623 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, varscan2
- OR56A4 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- PREX1 | c.2134A>G p.I712V | Missense Mutation (SNP) | VAF 141/446 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RPS6KA2 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2
- RYR2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RYR3 | c.3527T>G p.L1176R | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SBK3 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 56/640 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SEMA5B | c.1319G>C p.R440P | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SERPINA11 | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SLC39A7 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 81/755 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TARS1 | c.1834T>G p.W612G | Missense Mutation (SNP) | VAF 176/286 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TDG | c.913A>C p.N305H | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2
- TNXB | c.12089C>A p.A4030E (on ENST00000647633; = p.A3783E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/465 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TREM1 | c.685A>C p.S229R | Missense Mutation (SNP) | VAF 89/585 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC27 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.89591A>G p.N29864S (on ENST00000591111; = p.N22440S on NM_003319.4) | Missense Mutation (SNP) | VAF 61/212 reads (29%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.81788A>G p.Y27263C (on ENST00000591111; = p.Y19839C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/156 reads (11%) | PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- UNC79 | c.7685del p.P2562Qfs*2 (on ENST00000393151 / NM_001346218.2; = p.P2385Qfs*2 on NM_020818.5) | Frame Shift Del (DEL) | VAF 102/308 reads (33%) | called by mutect2, pindel, varscan2
- WNK3 | c.3767del p.T1256Ifs*18 | Frame Shift Del (DEL) | VAF 55/168 reads (33%) | called by mutect2, pindel, varscan2
- XYLT2 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ZC3H4 | c.668_669dup p.L224Sfs*2 | Frame Shift Ins (INS) | VAF 125/298 reads (42%) | called by mutect2, pindel, varscan2
- ZFX | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF469 | c.3677G>T p.G1226V (on ENST00000437464; = p.G1254V on NM_001367624.2) | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF568 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- ABL1 | c.1533G>A p.G511= | Silent (SNP) | VAF 13/262 reads (5%) | called by muse, mutect2
- ACBD3 | c.1341C>T p.V447= | Silent (SNP) | VAF 84/411 reads (20%) | called by muse, mutect2, varscan2
- ACTL9 | c.1146C>T p.I382= | Silent (SNP) | VAF 78/293 reads (27%) | catalogued as COSV61006667; called by muse, mutect2, varscan2
- ADRA2A | c.54C>T p.S18= | Silent (SNP) | VAF 87/275 reads (32%) | called by muse, mutect2, varscan2
- AKT2 | c.630G>A p.P210= | Silent (SNP) | VAF 76/348 reads (22%) | catalogued as rs779762305; called by muse, mutect2, varscan2
- BSN | c.6225A>G p.P2075= | Silent (SNP) | VAF 182/352 reads (52%) | called by muse, mutect2, varscan2
- CTNNA2 | c.966C>T p.C322= | Silent (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- DGKI | c.2766A>G p.P922= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as COSV55978164; called by muse, mutect2, varscan2
- DNAH7 | c.7902T>A p.S2634= | Silent (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- DNAJC16 | c.54G>A p.L18= | Silent (SNP) | VAF 53/224 reads (24%) | catalogued as COSV61601934; called by muse, mutect2, varscan2
- DOCK9 | c.192C>T p.I64= (on ENST00000376460 / NM_001366676.2; = p.I65= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/317 reads (9%) | called by muse, mutect2
- DPYSL2 | c.1320C>T p.R440= | Silent (SNP) | VAF 56/241 reads (23%) | catalogued as rs144002094; called by muse, mutect2, varscan2
- FZD9 | c.1101G>A p.A367= | Silent (SNP) | VAF 115/322 reads (36%) | catalogued as rs782140617, COSV60670140; called by muse, mutect2, varscan2
- IGSF9B | c.900G>A p.K300= | Silent (SNP) | VAF 80/406 reads (20%) | called by muse, mutect2, varscan2
- KCNV1 | c.814A>C p.R272= | Silent (SNP) | VAF 81/421 reads (19%) | catalogued as COSV52089305; called by muse, mutect2, varscan2
- LTBP2 | c.3147C>T p.C1049= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs768541799; called by muse, mutect2, varscan2
- LTN1 | c.3696G>T p.L1232= | Silent (SNP) | VAF 10/241 reads (4%) | called by muse, mutect2
- MTNR1B | c.39G>A p.A13= | Silent (SNP) | VAF 50/508 reads (10%) | catalogued as rs755871864; called by muse, mutect2
- MYO9B | c.3435G>C p.R1145= | Silent (SNP) | VAF 37/357 reads (10%) | called by muse, mutect2, varscan2
- MYT1L | c.3189C>A p.I1063= | Silent (SNP) | VAF 34/179 reads (19%) | catalogued as rs1289911606, COSV67704225; called by muse, mutect2, varscan2
- NAMPT | c.933A>G p.R311= | Silent (SNP) | VAF 59/223 reads (26%) | called by muse, mutect2, varscan2
- OR14I1 | c.528C>T p.F176= | Silent (SNP) | VAF 19/648 reads (3%) | catalogued as COSV61199624; called by muse, mutect2
- OR2T12 | c.21C>T p.T7= | Silent (SNP) | VAF 58/459 reads (13%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2571C>T p.S857= | Silent (SNP) | VAF 40/662 reads (6%) | catalogued as rs530854246; called by muse, mutect2
- PIWIL4 | c.1239C>G p.R413= | Silent (SNP) | VAF 30/418 reads (7%) | called by muse, mutect2
- PLEKHF1 | c.312G>A p.T104= | Silent (SNP) | VAF 44/1774 reads (2%) | catalogued as rs1317967017; called by muse, mutect2
- PLEKHG2 | c.954C>T p.G318= | Silent (SNP) | VAF 48/1109 reads (4%) | catalogued as rs754076614, COSV52683851; called by muse, mutect2
- PRKN | c.357G>A p.L119= | Silent (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- PTPRJ | c.2205C>T p.A735= | Silent (SNP) | VAF 107/322 reads (33%) | called by muse, mutect2, varscan2
- RBP3 | c.706A>C p.R236= | Silent (SNP) | VAF 23/398 reads (6%) | called by muse, mutect2
- RNFT1 | c.1014A>G p.E338= | Silent (SNP) | VAF 30/166 reads (18%) | catalogued as rs769586740, COSV59869520; called by muse, mutect2, varscan2
- SCFD1 | c.21G>A p.A7= | Silent (SNP) | VAF 89/330 reads (27%) | catalogued as rs546812026; called by mutect2, varscan2
- SLC12A7 | c.2889G>A p.A963= | Silent (SNP) | VAF 42/738 reads (6%) | catalogued as rs762187116, COSV53761061; called by muse, mutect2
- SNAP47 | c.927C>T p.Y309= | Silent (SNP) | VAF 83/458 reads (18%) | catalogued as rs548643206; called by muse, varscan2
- SPDYE1 | c.175C>T p.L59= | Silent (SNP) | VAF 87/473 reads (18%) | called by muse, mutect2, varscan2
- TDRD6 | c.111C>T p.G37= | Silent (SNP) | VAF 134/683 reads (20%) | called by muse, mutect2, varscan2
- TENM3 | c.3804C>T p.D1268= | Silent (SNP) | VAF 81/255 reads (32%) | catalogued as rs369770052; called by muse, mutect2, varscan2
- TMC6 | c.1020C>G p.P340= | Silent (SNP) | VAF 76/282 reads (27%) | called by mutect2, varscan2
- USP34 | c.8055T>C p.A2685= | Silent (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- WDR62 | c.3063G>A p.T1021= | Silent (SNP) | VAF 30/566 reads (5%) | catalogued as rs750350692; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- WSCD2 | c.1209C>T p.S403= | Silent (SNP) | VAF 52/333 reads (16%) | catalogued as rs1306792625, COSV54583324; called by muse, mutect2, varscan2
- ZNF71 | c.48C>T p.S16= | Silent (SNP) | VAF 39/378 reads (10%) | catalogued as rs201318196, COSV60148052; called by muse, mutect2, varscan2
- ENDOV | c.838+261G>A | Intron (SNP) | VAF 218/364 reads (60%) | catalogued as rs1268338591; called by muse, mutect2, varscan2
- FYTTD1 | c.104-592A>C | Intron (SNP) | VAF 63/294 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23435G>C | Intron (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- PAXIP1 | chr7:155004188 G>A | 5'Flank (SNP) | VAF 66/254 reads (26%) | catalogued as rs560551672; called by muse, mutect2, varscan2
- PKHD1 | c.10156+22381T>C | Intron (SNP) | VAF 32/361 reads (9%) | catalogued as COSV100582690; called by muse, mutect2
- ZNF717 | chr3:75732116 T>G | 3'Flank (SNP) | VAF 24/226 reads (11%) | called by muse, mutect2, varscan2
